Somatic mutation profile of tumor specimen C3L-08633-01 (aliquot CPT0479950009) from CPTAC case C3L-08633, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-08633-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef54c5d7-d900-4968-b162-ddb27a4946a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08633-31 (Blood Derived Normal), aliquot CPT0480100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ba2b205-fc73-46a2-b7da-5ce882eb49d3

The open-access MAF lists 90 somatic variants for this specimen: 64 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 22, Nonsense Mutation 2, Intron 2, 5'UTR 1, In Frame Del 1, Translation Start Site 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- AFP | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs149074640; called by muse, mutect2
- AKAP17A | c.1152+6C>T | Splice Region (SNP) | VAF 52/558 reads (9%) | catalogued as rs377052727; called by muse, mutect2
- APBA3 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 29/464 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs1397936632, COSV57462173; called by muse, mutect2
- CCDC73 | c.2394G>A p.M798I | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs866552882; called by muse, mutect2
- CLCA4 | c.2044G>A p.G682R | Missense Mutation (SNP) | VAF 36/530 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as COSV99760340; called by muse, mutect2
- CNOT2 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as rs1271903477; called by muse, mutect2
- CYP2C19 | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1373273817, COSV64908271; called by muse, mutect2
- DNAH5 | c.1339C>T p.H447Y | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99446950; called by muse, mutect2
- EPHA3 | c.1172A>G p.N391S | Missense Mutation (SNP) | VAF 25/382 reads (7%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as rs1270503537, COSV60695562; called by muse, mutect2
- ERICH4 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV55728715; called by muse, mutect2
- FAT3 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53109483; called by muse, mutect2
- HSPG2 | c.1940G>T p.R647L | Missense Mutation (SNP) | VAF 31/524 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65973764; called by muse, mutect2
- JPH4 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 31/536 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV62509075; called by muse, mutect2
- JRK | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 15/410 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as rs1405928839, COSV101401026; called by muse, mutect2
- KCNQ2 | c.1159C>T p.P387S (on ENST00000359125 / NM_172107.4; = p.P377S on NM_004518.6) | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs747158839; called by muse, mutect2
- MAGEA4 | c.816C>A p.F272L | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99367707; called by muse, mutect2, varscan2
- MYO7A | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV68687098; called by muse, mutect2
- NECTIN4 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs558365881, COSV63512770, COSV63513181; called by muse, mutect2, varscan2
- OR10H3 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.364); catalogued as COSV59944009; called by muse, mutect2
- OR6P1 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 51/480 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV58110784; called by muse, mutect2, varscan2
- PLA2G2D | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV64281463; called by muse, mutect2
- PPP4R3C | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); catalogued as rs1480579407; called by muse, mutect2, varscan2
- ROS1 | c.4237G>A p.G1413R | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs928456849; called by muse, mutect2
- SCARA5 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 42/552 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs766861715, COSV57276546; called by muse, mutect2
- SLC26A11 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 40/576 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63278796; called by muse, mutect2
- TET2 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1343883865; called by muse, mutect2
- TNRC6B | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV57307636; called by muse, mutect2
- WHAMM | c.1444C>T p.L482F | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99724910; called by muse, mutect2
- ZNF229 | c.2023C>T p.Q675* | Nonsense Mutation (SNP) | VAF 14/408 reads (3%) | catalogued as COSV52163262; called by muse, mutect2
- ZNF560 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.125); catalogued as COSV56869857; called by muse, mutect2
- ABCC4 | c.2281C>T p.L761F | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.835); called by muse, mutect2
- AMBP | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 27/355 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ART4 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 19/411 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.132); called by muse, mutect2
- ASTN1 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 48/544 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2
- BEGAIN | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 45/526 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- C8orf33 | c.629T>A p.I210K | Missense Mutation (SNP) | VAF 50/622 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2
- C8orf34 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 25/329 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- CAGE1 | c.2120C>T p.S707L (on ENST00000512086; = p.S571L on NM_205864.3) | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDKN2A | c.100G>C p.A34P | Missense Mutation (SNP) | VAF 45/482 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- CFAP299 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); called by muse, mutect2
- CR1 | c.2343C>G p.D781E | Missense Mutation (SNP) | VAF 54/636 reads (8%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.971); called by muse, mutect2
- CUL9 | c.4876C>T p.P1626S | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- DBX2 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- DNMBP | c.1954C>G p.Q652E | Missense Mutation (SNP) | VAF 13/409 reads (3%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.104); called by muse, mutect2
- ELMOD3 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- EPAS1 | c.2483G>A p.G828E | Missense Mutation (SNP) | VAF 13/307 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2
- ERCC8 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 24/411 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.115); called by muse, mutect2
- FREM1 | c.3817G>A p.D1273N | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR151 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 35/488 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- HPS5 | c.1914G>A p.M638I (on ENST00000349215 / NM_181507.2; = p.M524I on NM_007216.4) | Missense Mutation (SNP) | VAF 30/427 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- KIF19 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- KLHL35 | c.318_320del p.L107del | In Frame Del (DEL) | VAF 46/509 reads (9%) | called by mutect2, pindel
- LHX3 | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 36/441 reads (8%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.074); called by muse, mutect2
- LTBP1 | c.4139G>A p.W1380* (on ENST00000404816 / NM_206943.4; = p.W1054* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 32/460 reads (7%) | called by muse, mutect2
- LTBP2 | c.2389G>T p.V797F | Missense Mutation (SNP) | VAF 11/365 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.168); called by muse, mutect2
- MPDU1 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR4E1 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2
- PTPRM | c.2516C>T p.S839F | Missense Mutation (SNP) | VAF 13/317 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); called by muse, mutect2
- TRAV26-2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/323 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2
- TSPOAP1 | c.5464C>A p.P1822T | Missense Mutation (SNP) | VAF 39/397 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VWDE | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 29/406 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- VWDE | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 29/414 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- ZHX3 | c.1766C>G p.P589R | Missense Mutation (SNP) | VAF 20/397 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.206); called by muse, mutect2
- ADAM32 | c.1719C>T p.F573= | Silent (SNP) | VAF 32/473 reads (7%) | catalogued as rs373986488; called by muse, mutect2
- CYP7A1 | c.564T>C p.F188= | Silent (SNP) | VAF 38/439 reads (9%) | called by muse, mutect2
- E2F7 | c.2464C>T p.L822= | Silent (SNP) | VAF 44/512 reads (9%) | called by muse, mutect2
- GLRA4 | c.123C>T p.P41= | Silent (SNP) | VAF 33/219 reads (15%) | called by muse, mutect2, varscan2
- KIF19 | c.495C>T p.S165= | Silent (SNP) | VAF 15/356 reads (4%) | catalogued as rs1299460989, COSV100739175; called by muse, mutect2
- MAGI1 | c.711G>A p.E237= | Silent (SNP) | VAF 32/420 reads (8%) | catalogued as COSV58316689; called by muse, mutect2
- NUDT14 | c.588G>A p.P196= | Silent (SNP) | VAF 28/463 reads (6%) | catalogued as rs765818744; called by muse, mutect2
- OBSCN | c.16146G>A p.V5382= | Silent (SNP) | VAF 47/462 reads (10%) | called by muse, mutect2
- PATJ | c.4842C>T p.L1614= | Silent (SNP) | VAF 18/354 reads (5%) | catalogued as COSV57157520; called by muse, mutect2
- PATL2 | c.1203C>T p.V401= | Silent (SNP) | VAF 34/376 reads (9%) | catalogued as COSV71384731; called by muse, mutect2
- PCDHB2 | c.2049C>T p.A683= | Silent (SNP) | VAF 50/910 reads (5%) | catalogued as rs146418411; called by muse, mutect2
- PKHD1L1 | c.11601C>T p.V3867= | Silent (SNP) | VAF 20/298 reads (7%) | called by muse, mutect2
- POU5F1B | c.141C>T p.I47= | Silent (SNP) | VAF 56/698 reads (8%) | catalogued as rs775246122, COSV66966854; called by muse, mutect2
- RBM15 | c.1440C>T p.T480= | Silent (SNP) | VAF 17/420 reads (4%) | called by muse, mutect2
- SLC6A3 | c.426C>T p.G142= | Silent (SNP) | VAF 21/351 reads (6%) | called by muse, mutect2
- SLITRK6 | c.1257T>C p.N419= | Silent (SNP) | VAF 26/346 reads (8%) | called by muse, mutect2
- SPG11 | c.6318C>T p.S2106= | Silent (SNP) | VAF 14/388 reads (4%) | catalogued as rs1481219864; called by muse, mutect2
- TENM4 | c.7860G>A p.V2620= | Silent (SNP) | VAF 25/466 reads (5%) | called by muse, mutect2
- TMEM252 | c.442A>C p.R148= | Silent (SNP) | VAF 18/413 reads (4%) | called by muse, mutect2
- VPS53 | c.825C>T p.N275= (on ENST00000571805 / NM_001366253.2; = p.N246= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- ZHX3 | c.1767G>C p.P589= | Silent (SNP) | VAF 22/396 reads (6%) | called by muse, mutect2
- ZNF536 | c.2271G>A p.G757= | Silent (SNP) | VAF 32/424 reads (8%) | catalogued as COSV62819373; called by muse, mutect2
- ARMCX4 | c.1038+1493T>C | Intron (SNP) | VAF 44/303 reads (15%) | called by muse, mutect2, varscan2
- CCDC24 | c.-156C>A | 5'UTR (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- CTAGE1 | c.*922G>A | 3'UTR (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- SYT7 | c.215+5219G>A | Intron (SNP) | VAF 36/464 reads (8%) | catalogued as rs1416681456; called by muse, mutect2
